CCDI case PBCLIW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Bones, joints and articular cartilage of other and unspecified sites.
https://portal.gdc.cancer.gov/cases/03a8a358-06a1-415a-8902-e6c809346924

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Head, face or neck, NOS; Age at diagnosis: 3.9 years (1,433 days).

Biospecimens (3 samples)
- Sample 0DUVT1: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DUVTA: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DUVTU: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
